Surgical pathology report (de-identified scan), TCGA case TCGA-B5-A0JT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Duke, specimen TCGA-B5-A0JT-01A (Primary Tumor).

[page 1 of 2]
Malignant neoplasm corpus uteri.

PCGA-B5-A0JT-01A-PR 01/10/10

A2- anterior cervix
A3- anterior lower uterine segment/upper endocervical canal
A4- posterior cervix
A5- posterior lower uterine segment/upper endocervical canal
A6-7 anterior endomyometrial mass at cornu
A8- posterior endomyometrial mass at cornu
A9- anterior endomyometrium with mass
A10- posterior endometrium with mass

The right adnexa is composed of a 4.5 cm long, 0.5 cm in diameter fimbriated fallopian tube with attached mesentery and an attached 2 x 1.3 x 1.3 cm cerebriform white-tan ovary. Sectioning of the adnexa demonstrates a grossly unremarkable cut surface. Representative sections are submitted in block A12.

B. "Left pelvic node", received fresh and placed in formalin is a 12 x 8 x 4 cm aggregate of yellow-tan fibrofatty tissue which is dissected for adherent lymph node candidates. Ten lymph node candidates are identified from 0.3 to 2.4 cm in greatest dimension are submitted as follows:

- ```

B1- three lymph node candidates
B2- three lymph node candidates
B3- one lymph node candidate, bisected
B4- one lymph node candidate, bisected
B5- one lymph node candidate, bisected
B6-7 largest lymph node candidate, bisected

```

C. "Right pelvic node", received fresh and placed in formalin is a 9 x 7 x 3 cm aggregate of pink-tan soft tissue. The specimen is bisected for apparent lymph node candidates. Three lymph node candidates are identified from 0.6 cm in greatest dimension and are submitted as follows:

|----------------------------------|-----|--------------|
| Diagnosis Uncertainty            |     | X            |
| Primary Tumor Site Uncertainty   |     | X            |
| HRP Discrepancy                  |     | X            |
| Case is Eligible:                | 1   | DISQUALIFIED |
| Second Reviewer:                 |     |              |

[page 2 of 2]
- C1- one lymph node candidate
- C2- one lymph node candidate
- C3- largest lymph node candidate, bisected
- [REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Uterus, cervix, tubes and ovaries":

AF1 (mass deepest extension)-endometrioid adenocarcinoma, FIGO grade 1,
2 mm at region of cornu, 6 cm from serosa (Dr.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY, OOPHORECTOMY & LYMPH NODES

PATHOLOGIC STAGE (AJCC 6th Edition): pT1b pN0 pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. UTERUS: 52 GRAMS

ENDOMETRIUM:

TUMOR SITE: CORNU

HISTOLOGIC TYPE: ENDOMETRIOID ADENOCARCINOMA WITH FOCAL SQUAMOUS
DIFFERENTIATION.

FIGO GRADE: 1

TUMOR SIZE: 5 X 4.7 X 3 CM.

MAXIMUM DEPTH OF MYOMETRIAL INVASION: 0.2 CM, IN A 1.7 THICK WALL (IN
CORNU, WALL IS 0.9 CM THICK).

LYMPHATIC/VASCULAR INVASION: NEGATIVE

ADJACENT NON-NEOPLASTIC ENDOMETRIUM: QUIESCENT

REMAINING MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS.

CERVIX: NO PATHOLOGIC DIAGNOSIS.

THE FOLLOWING SPECIMENS ARE FREE OF TUMOR:

A. LEFT OVARY: ENDOMETRIOSIS.

A. RIGHT OVARY AND BOTH FALLOPIAN TUBES: NO PATHOLOGIC DIAGNOSIS.

B. LEFT PELVIC LYMPH NODES: NO TUMOR IN 11 LYMPH NODES (0/11).

C. RIGHT PELVIC LYMPH NODES: NO TUMOR IN 3 LYMPH NODES (0/3).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 39302525-bfff-4ef3-83aa-57854dc69f73 (TCGA-B5-A0JT.CC6EE5B1-5548-4DE7-873F-332DBF81710F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).